Gene-level copy-number profile of tumor specimen TCGA-02-0321-01A from TCGA case TCGA-02-0321, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.3 years (27,125 days).
Specimen TCGA-02-0321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.4ac9f5f8-0b11-4e21-b467-833f9aea448e.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,149 have no estimate.
https://portal.gdc.cancer.gov/files/49846940-d48e-43ef-a6ac-deab41d32141

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 8,881; copy number 2: 43,192; copy number 3: 3,358; copy number 4: 1; copy number 11: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0321-01): tumor purity 0.46, ploidy 1.92, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,099,430–79,212,667, 1 gene (within-gene range 0–1): WWOX.
- chr16:78,495,926–79,078,234, 13 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:151,806,490–153,144,588, 28 genes, copy number 11: AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5, Metazoa_SRP, GALNT11, AC006017.1, YBX1P4, KMT2C, AC104692.2, AC104692.1, SEPTIN7P6, Y_RNA, FABP5P3, CCT8L1P, LINC01003, AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P, ACTR3B, AC006348.1, AC079809.1.

Autosomal genes at a single copy (total copy number 1): 8,881. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
